Somatic mutation profile of tumor specimen MMRF_1572_1_BM_CD138pos (aliquot MMRF_1572_1_BM_CD138pos_T1_KBS5U_L03483) from MMRF case MMRF_1572, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.8 years (25,141 days).
Specimen MMRF_1572_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9566e7f-1959-4f5c-a59b-7958c46567f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1572_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1572_1_PB_Whole_C2_KBS5U_L03495; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/223eec15-0001-4453-862a-31148c730aa7

The open-access MAF lists 139 somatic variants for this specimen: 57 protein-altering or splice-affecting, 23 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 40, Silent 23, Intron 10, 5'UTR 4, RNA 2, 5'Flank 2, Splice Site 2, 3'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137852569, CM920071, COSV65954647; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1178102908; called by muse, mutect2
- BSN | c.6521G>T p.G2174V | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as COSV56513965; called by muse, mutect2, varscan2
- BSN | c.6919C>T p.R2307W | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs768774052, COSV99607149; called by muse, mutect2, varscan2
- CYP4A22 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); catalogued as COSV99595250; called by muse, mutect2
- FAT1 | c.12608G>A p.R4203H | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs200185840, COSV71673653; called by muse, mutect2
- FER1L5 | c.3986C>T p.T1329M (on ENST00000623019; = p.T1302M on NM_001293083.2) | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs769615665; called by muse, mutect2, varscan2
- GNL3 | c.57del p.Y19* | Frame Shift Del (DEL) | VAF 131/334 reads (39%) | catalogued as COSV66921029; called by mutect2, pindel, varscan2
- IGHV2-70 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs369592881; called by muse, varscan2
- IGHV2-70 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs373084365; called by muse, varscan2
- IGHV6-1 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs782770152; called by muse, mutect2, varscan2
- IGLV3-1 | c.302A>T p.E101V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs532827838; called by muse, varscan2
- IGLV3-1 | c.336C>G p.S112R | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs73880716; called by muse, varscan2
- LCN10 | c.517G>A p.V173I (on ENST00000474369 / NM_001368089.1; = p.V186I on NM_001001712.3) | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs536082781; called by muse, mutect2, varscan2
- LRFN5 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as rs1436896951, COSV99982009; called by muse, mutect2, varscan2
- MAX | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, mutect2, varscan2
- MAX | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV52416961; called by muse, mutect2, varscan2
- MUC3A | c.1091A>G p.E364G | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated, low confidence (0.15); catalogued as COSV60209477, COSV60223931; called by muse, mutect2, varscan2
- NOS3 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.782); catalogued as COSV52489857; called by muse, mutect2, varscan2
- PCLO | c.4165C>A p.L1389I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV100433670; called by muse, mutect2, varscan2
- PFKFB3 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | PolyPhen benign (0.017); catalogued as COSV57987539, COSV57988137; called by muse, mutect2, varscan2
- SI | c.3232C>T p.R1078W | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769259229, COSV52270933, COSV52283854; called by muse, mutect2, varscan2
- SLC17A1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs764256908; called by muse, mutect2, varscan2
- SZT2 | c.8076C>G p.I2692M (on ENST00000634258 / NM_001365999.1; = p.I2635M on NM_015284.4) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV65169796; called by muse, mutect2, varscan2
- TRPV4 | c.1891+1G>A p.X631_splice | Splice Site (SNP) | VAF 6/76 reads (8%) | catalogued as rs1376567448; called by muse, mutect2
- TTLL5 | c.3823+1G>T p.X1275_splice | Splice Site (SNP) | VAF 3/44 reads (7%) | catalogued as rs1292821501; called by muse, mutect2
- VIPR2 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1157096085, COSV51106132; called by muse, mutect2, varscan2
- ZNF25 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1259014264; called by muse, mutect2, varscan2
- ADAM23 | c.1823A>G p.D608G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- AKAP12 | c.3282G>C p.L1094F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- BCHE | c.1611A>T p.R537S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2
- CDHR3 | c.792T>G p.D264E | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIS3 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ERN1 | c.476C>G p.T159R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM76B | c.237dup p.A80Cfs*25 | Frame Shift Ins (INS) | VAF 77/363 reads (21%) | called by mutect2, pindel, varscan2
- FAT3 | c.3016T>G p.Y1006D | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GLRX2 | c.376G>A p.V126I (on ENST00000367439 / NM_197962.3; = p.V127I on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- H2BC11 | c.329A>G p.H110R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- IGHV6-1 | c.110C>G p.T37S | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- IGKV4-1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC63 | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- MAMDC2 | c.462C>G p.S154R | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- MUC15 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NDST4 | c.1538T>C p.I513T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- OR4D5 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PCED1A | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDCD1 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLA2G5 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPRD1B | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SEC23A | c.821T>A p.L274Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEMA3A | c.1150A>C p.K384Q | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SETX | c.4679A>G p.N1560S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIGLEC1 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SLC30A5 | c.1667A>G p.H556R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TRAF3 | c.1628T>A p.L543Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USF2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- ZNF10 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- CAMK1 | c.1089C>T p.S363= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- DOCK5 | c.5466C>G p.P1822= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV52402219; called by muse, mutect2, varscan2
- HMCN1 | c.1665G>A p.R555= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as rs1172919370; called by muse, mutect2, varscan2
- IGHV1-69 | c.336G>A p.V112= | Silent (SNP) | VAF 50/72 reads (69%) | catalogued as rs782427576; called by muse, mutect2, varscan2
- IGHV1-69D | c.336G>A p.V112= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.90G>A p.L30= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as rs564942249; called by muse, varscan2
- IGLL5 | c.114G>A p.L38= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs556230331, COSV73249618, COSV73250730; called by mutect2, varscan2
- IGLV3-1 | c.345C>T p.H115= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs778942547; called by muse, varscan2
- INO80 | c.546A>G p.Q182= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs1410578562; called by muse, mutect2, varscan2
- LRRK1 | c.1056A>G p.S352= | Silent (SNP) | VAF 68/152 reads (45%) | called by muse, mutect2, varscan2
- LTN1 | c.2008C>T p.L670= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- MTOR | c.3513C>T p.S1171= | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- MTOR | c.1002G>A p.L334= | Silent (SNP) | VAF 55/132 reads (42%) | catalogued as rs754251747, COSV63879555; called by muse, mutect2, varscan2
- NME8 | c.1404G>A p.Q468= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV52255271; called by muse, mutect2, varscan2
- NME8 | c.1587T>A p.V529= | Silent (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- PIM1 | c.78G>C p.A26= | Silent (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- PPP4R3C | c.2400T>C p.H800= | Silent (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- PTGDR | c.918C>G p.L306= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV100035698; called by muse, mutect2, varscan2
- RFX2 | c.84C>T p.S28= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100353499; called by muse, mutect2
- SMG8 | c.2610A>C p.V870= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs1165889264; called by muse, mutect2, varscan2
- TBX2 | c.225G>T p.L75= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs1366585436; called by muse, mutect2, varscan2
- WNT5B | c.774C>G p.T258= | Silent (SNP) | VAF 23/88 reads (26%) | called by muse, varscan2
- WNT5B | c.909C>G p.L303= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV60198282; called by muse, varscan2
- ABI2 | c.*4425G>T | 3'UTR (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- AQP1 | c.*966_*969dup | 3'UTR (INS) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- B3GLCT | c.*418A>C | 3'UTR (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- BICRAL | c.*2468T>A | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- BTG1 | c.*134G>C | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- C2orf88 | c.*871T>A | 3'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- CCDC85C | c.*13054A>C | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- CD164 | c.-88G>A | 5'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as rs1321820307, COSV99248791; called by muse, mutect2, varscan2
- CHDH | c.*186C>T | 3'UTR (SNP) | VAF 7/81 reads (9%) | catalogued as rs1351263006; called by muse, mutect2
- CPN1 | c.-79A>G | 5'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- CUX1 | c.*5615T>G | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2
- DAAM2 | c.*398T>A | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- DHRSX | c.*581C>G | 3'UTR (SNP) | VAF 36/478 reads (8%) | called by muse, mutect2
- DUSP4 | c.*648C>T | 3'UTR (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- DYDC1 | c.*43A>C | 3'UTR (SNP) | VAF 11/249 reads (4%) | called by muse, mutect2
- ENTPD5 | c.*427C>T | 3'UTR (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- FILIP1L | c.605+25997C>T | Intron (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- GANAB | c.*512C>T | 3'UTR (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- GOLM2 | c.*1739C>T | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- GPR158 | c.*2568G>C | 3'UTR (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100892637; called by muse, mutect2, varscan2
- GRIA1 | c.-146C>T | 5'UTR (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- GRIK2 | c.*1561del | 3'UTR (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel
- GTPBP10 | c.-32A>T | 5'UTR (SNP) | VAF 22/218 reads (10%) | called by muse, mutect2
- HDAC2 | c.358+66T>A | Intron (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- HSD17B4 | c.1929+56G>A | Intron (SNP) | VAF 16/112 reads (14%) | called by muse, varscan2
- HTR4 | c.*925A>C | 3'UTR (SNP) | VAF 53/92 reads (58%) | called by muse, mutect2, varscan2
- KLHL8 | c.*2737A>T | 3'UTR (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- LTN1 | c.*950G>A | 3'UTR (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- MAP1B | c.*3387T>G | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- MAST4 | c.675-49606G>C | Intron (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- MLLT3 | c.*2329A>G | 3'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- MS4A4A | c.*51G>A | 3'UTR (SNP) | VAF 28/337 reads (8%) | called by muse, mutect2
- NANOS3 | chr19:13874774 G>A | 5'Flank (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- NFIB | c.*4622T>C | 3'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- NPAP1 | c.*2479_*2480insGATAGATAGATAGATA | 3'UTR (INS) | VAF 3/33 reads (9%) | called by pindel, varscan2*
- NPM1 | c.771+46G>A | Intron (SNP) | VAF 75/193 reads (39%) | called by muse, mutect2, varscan2
- PBX3 | c.*208A>C | 3'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- PCGF5 | c.*1630A>G | 3'UTR (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- PNRC2P1 | n.38A>C | RNA (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- PRF1 | c.*363A>G | 3'UTR (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- PSMC2 | c.*720A>G | 3'UTR (SNP) | VAF 19/97 reads (20%) | catalogued as rs567794252; called by muse, mutect2, varscan2
- PUF60 | chr8:143829696 G>T | 5'Flank (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- SEMA3E | c.*3019A>C | 3'UTR (SNP) | VAF 55/106 reads (52%) | called by muse, mutect2, varscan2
- SERP1 | c.*780C>T | 3'UTR (SNP) | VAF 10/150 reads (7%) | catalogued as rs1214032040; called by muse, mutect2
- SP140L | c.*58C>T | 3'UTR (SNP) | VAF 32/392 reads (8%) | catalogued as COSV99707180; called by muse, mutect2
- SPARCL1 | c.*331G>T | 3'UTR (SNP) | VAF 9/87 reads (10%) | catalogued as rs948165485; called by muse, mutect2, varscan2
- STK24 | c.1295+1321G>A | Intron (SNP) | VAF 27/69 reads (39%) | catalogued as rs1380532980; called by muse, mutect2, varscan2
- TEAD1 | c.*4193A>C | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- TLE3 | c.*225C>T | 3'UTR (SNP) | VAF 24/111 reads (22%) | catalogued as rs1257570502; called by muse, mutect2, varscan2
- TMEM144 | c.109+448A>T | Intron (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- TRIM7 | c.619-765T>C | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- TTC14 | c.1291-38T>G | Intron (SNP) | VAF 63/337 reads (19%) | called by muse, mutect2, varscan2
- UBE2E2 | c.*1230C>T | 3'UTR (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- VASH2 | chr1:212989885 ins A | 3'Flank (INS) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- WNT2 | c.*85G>C | 3'UTR (SNP) | VAF 48/263 reads (18%) | called by muse, mutect2, varscan2
- ZC3H12D | c.787+74A>C | Intron (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- ZMYND11 | c.*223A>G | 3'UTR (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- ZNF268 | c.*6326A>C | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ZNF725P | n.180C>G | RNA (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
